Gene-level copy-number profile of tumor specimen TCGA-DD-A4NR-01A from TCGA case TCGA-DD-A4NR, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 85.9 years (31,386 days).
Specimen TCGA-DD-A4NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.31fd6231-5c16-408f-a94c-63e6b96307d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A4NR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/949611c3-c0c9-46ea-9847-a3135f4018ba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,258; copy number 4: 47,923; copy number 5: 114; copy number 6: 8,975; copy number 8: 74; copy number 10: 4; copy number 11: 76; copy number 15: 23; copy number 16: 96; copy number 20: 61; copy number 22: 1; copy number 24: 69; copy number 27: 45; copy number 28: 30; copy number 34: 36; copy number 37: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A4NR-01A-11D-A30U-01): tumor purity 0.35, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 476 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:63,215,981–68,293,818, 79 genes, copy number 11–15 (broad region; genes not listed).
- chr8:69,834,111–75,566,834, 106 genes, copy number 10–34 (within-gene range 8–34) (broad region; genes not listed).
- chr8:100,337,595–104,589,024, 108 genes, copy number 20–24 (broad region; genes not listed).
- chr8:104,699,479–104,703,555, 1 gene, copy number 24: AC012564.1.
- chr8:117,128,455–128,564,679, 176 genes, copy number 16–37 (broad region; genes not listed).
- chr8:130,780,301–131,432,869, 6 genes, copy number 11–24: ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
